Gene-level copy-number profile of tumor specimen ALCH-B3IV-TTP1-A from ALCHEMIST case ALCH-B3IV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.4 years (24,603 days).
Specimen ALCH-B3IV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dcf0d1d4-8c2f-4fc3-a0b7-21cf89dfe708.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3IV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/7cbefe4a-5871-4219-887c-cd2933fc57f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 1,146; copy number 2: 50,598; copy number 3: 6,498; copy number 4: 116.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,713,576–97,739,862, 1 gene: ZAP70.
- chr2:219,482,073–219,516,877, 1 gene (within-gene range 0–2): ASIC4-AS1.
- chr2:219,498,884–219,571,859, 8 genes (within-gene range 0–2): GMPPA, ASIC4, CHPF, TMEM198, AC009955.3, MIR3132, OBSL1, AC009955.4.
- chr2:241,675,747–242,175,634, 25 genes: DTYMK, ING5, AC114730.3, D2HGDH, AC114730.1, AC114730.2, GAL3ST2, AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5, LINC01237, FAM240C, LINC01238, AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2, RPL23AP88.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,142. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
